Somatic mutation profile of tumor specimen TCGA-36-2530-01A (aliquot TCGA-36-2530-01A-01D-1526-09) from TCGA case TCGA-36-2530, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 38.0 years (13,885 days).
Specimen TCGA-36-2530-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5c31067-a1bd-4d91-a375-8bbe87ecbb8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-36-2530-10A (Blood Derived Normal), aliquot TCGA-36-2530-10A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6eb15f04-d32e-4ff5-ae60-115f25999517

The open-access MAF lists 77 somatic variants for this specimen: 63 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 51, Silent 14, Splice Site 5, Nonsense Mutation 2, In Frame Del 2, Frame Shift Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 123/132 reads (93%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TPO | c.2395G>A p.E799K | Missense Mutation (SNP) | VAF 56/293 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs121908085, CM951242, COSV61110997; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC005324.2 | c.743C>G p.A248G | Missense Mutation (SNP) | VAF 170/194 reads (88%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.442); catalogued as COSV60888409; called by muse, mutect2, varscan2
- ANKRD16 | c.871C>G p.Q291E | Missense Mutation (SNP) | VAF 76/224 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.03); catalogued as COSV51948727; called by muse, mutect2, varscan2
- ATPAF2 | c.83G>A p.S28N | Missense Mutation (SNP) | VAF 13/15 reads (87%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.003); catalogued as rs375062622; called by muse, mutect2, varscan2
- BCL2L14 | c.614A>T p.E205V | Missense Mutation (SNP) | VAF 76/178 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV53794336; called by muse, mutect2, varscan2
- BTG3 | c.589C>T p.R197* | Nonsense Mutation (SNP) | VAF 90/101 reads (89%) | catalogued as rs373951463, COSV60286895; called by muse, mutect2, varscan2
- CASP1 | c.127G>C p.V43L | Missense Mutation (SNP) | VAF 607/931 reads (65%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV62057476; called by muse, mutect2, varscan2
- CCDC80 | c.111A>T p.K37N | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.193); catalogued as COSV52819812; called by muse, mutect2, varscan2
- CIAO3 | c.1361C>T p.A454V | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.445); catalogued as COSV52404472; called by muse, mutect2, varscan2
- COL17A1 | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 79/286 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV62229310; called by muse, mutect2, varscan2
- COLEC12 | c.1457C>A p.P486Q | Missense Mutation (SNP) | VAF 23/26 reads (88%) | SIFT tolerated (0.16); PolyPhen benign (0.38); catalogued as COSV68373826; called by muse, mutect2, varscan2
- CPN1 | c.343G>A p.V115I | Missense Mutation (SNP) | VAF 120/236 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs757656853, COSV64941891; called by muse, mutect2, varscan2
- CSPG4 | c.4537A>T p.I1513F | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV57900951; called by muse, mutect2, varscan2
- DDX18 | c.1696G>C p.E566Q | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV54306738; called by muse, mutect2, varscan2
- DDX31 | c.95G>A p.R32K | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV60139574; called by muse, mutect2, varscan2
- DNAJC25 | c.275G>C p.R92P | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.182); catalogued as COSV57957929; called by muse, mutect2, varscan2
- DNMT3A | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV53077231; called by muse, mutect2, varscan2
- ENAM | c.1834T>A p.S612T | Missense Mutation (SNP) | VAF 40/51 reads (78%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.709); catalogued as COSV68536985; called by muse, mutect2, varscan2
- ERO1B | c.828G>A p.W276* | Nonsense Mutation (SNP) | VAF 19/44 reads (43%) | catalogued as COSV51596930; called by muse, mutect2, varscan2
- EZH1 | c.1724A>C p.Y575S | Missense Mutation (SNP) | VAF 211/238 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV70550725; called by muse, mutect2, varscan2
- FAM78A | c.622A>G p.T208A | Missense Mutation (SNP) | VAF 83/235 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV55993255; called by muse, mutect2, varscan2
- GDF7 | c.1249C>A p.P417T | Missense Mutation (SNP) | VAF 78/113 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55348661; called by muse, mutect2, varscan2
- IKBKB | c.755C>T p.T252M | Missense Mutation (SNP) | VAF 251/283 reads (89%) | SIFT deleterious (0); PolyPhen benign (0.404); catalogued as rs374916045; called by muse, mutect2, varscan2
- KCNF1 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54462324; called by muse, mutect2, varscan2
- KDM4A | c.1283C>T p.T428M | Missense Mutation (SNP) | VAF 72/179 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.143); catalogued as rs757035656, COSV64960759; called by muse, mutect2, varscan2
- LHX2 | c.501G>C p.L167F | Missense Mutation (SNP) | VAF 50/78 reads (64%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.706); catalogued as COSV65319101; called by muse, mutect2, varscan2
- MAGT1 | c.102+1G>A p.X34_splice (on ENST00000618282 / NM_001367916.1; = p.X66_splice on NM_032121.5) | Splice Site (SNP) | VAF 114/199 reads (57%) | catalogued as COSV100800397; called by muse, mutect2, varscan2
- MAN1C1 | c.835-1G>T p.X279_splice | Splice Site (SNP) | VAF 67/79 reads (85%) | catalogued as COSV56048536; called by muse, mutect2, varscan2
- NCS1 | c.314T>G p.F105C | Missense Mutation (SNP) | VAF 274/784 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64963599; called by muse, mutect2, varscan2
- NUP50 | c.863T>A p.V288D | Missense Mutation (SNP) | VAF 7/161 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV100754382; called by muse, mutect2
- OR4D6 | c.322G>T p.G108C | Missense Mutation (SNP) | VAF 234/461 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV55660950; called by muse, mutect2, varscan2
- PDE4A | c.1464C>A p.T488= (on ENST00000380702 / NM_001111307.2; = p.T249= on NM_006202.3) | Splice Region (SNP) | VAF 39/83 reads (47%) | catalogued as COSV53362161; called by muse, mutect2, varscan2
- PLB1 | c.2422G>C p.A808P | Missense Mutation (SNP) | VAF 208/522 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.124); catalogued as COSV59835191; called by muse, mutect2, varscan2
- PLEKHA6 | c.2543G>T p.S848I | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.368); catalogued as COSV55339977, COSV99691913; called by muse, mutect2, varscan2
- POMGNT1 | c.784A>C p.N262H | Missense Mutation (SNP) | VAF 47/166 reads (28%) | PolyPhen probably damaging (0.921); catalogued as COSV64340908; called by muse, mutect2, varscan2
- PRKAR1B | c.765C>G p.I255M | Missense Mutation (SNP) | VAF 185/210 reads (88%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as COSV100816804; called by muse, varscan2
- PROS1 | c.1438G>C p.E480Q | Missense Mutation (SNP) | VAF 139/310 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as CD136315, COSV67777110; called by muse, mutect2, varscan2
- PUM1 | c.302G>A p.G101D | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as COSV57091072; called by mutect2, varscan2
- RAX | c.484G>C p.D162H | Missense Mutation (SNP) | VAF 55/61 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56875426; called by muse, mutect2, varscan2
- RGS12 | c.2266G>T p.A756S | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.748); catalogued as COSV58756907; called by muse, mutect2, varscan2
- RPH3A | c.1060G>A p.G354R (on ENST00000389385 / NM_001143854.2; = p.G350R on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 120/265 reads (45%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.631); catalogued as rs370825883; called by muse, mutect2, varscan2
- SETD1A | c.3176A>G p.E1059G | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.284); catalogued as COSV52692274; called by muse, mutect2, varscan2
- SPHKAP | c.1270G>T p.V424L | Missense Mutation (SNP) | VAF 84/169 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV60893552; called by muse, mutect2, varscan2
- SYT17 | c.332-1G>T p.X111_splice | Splice Site (SNP) | VAF 31/73 reads (42%) | catalogued as rs995771573, COSV62548167; called by muse, mutect2, varscan2
- TECTA | c.2782G>T p.G928W | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV50736053, COSV50801498; called by muse, mutect2, varscan2
- TENT5A | c.575T>G p.V192G | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60789493; called by muse, mutect2, varscan2
- TJP2 | c.1073C>T p.T358I | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55273996; called by muse, mutect2, varscan2
- TNFRSF10A | c.570C>G p.C190W | Missense Mutation (SNP) | VAF 209/462 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55327074; called by muse, mutect2, varscan2
- TP53 | c.723del p.C242Afs*5 | Frame Shift Del (DEL) | VAF 222/304 reads (73%) | catalogued as COSV53025058, COSV53153033, COSV53211006; called by mutect2, pindel, varscan2
- TPTE2 | c.1255A>T p.M419L (on ENST00000400230 / NM_199254.2; = p.M342L on NM_130785.3) | Missense Mutation (SNP) | VAF 135/301 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as COSV55027974; called by muse, mutect2, varscan2
- TRPA1 | c.1803G>C p.R601S | Missense Mutation (SNP) | VAF 115/275 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.079); catalogued as COSV51573757; called by muse, mutect2, varscan2
- TTN | c.4728A>C p.K1576N (on ENST00000591111; = p.K1530N on NM_003319.4) | Missense Mutation (SNP) | VAF 90/387 reads (23%) | PolyPhen benign (0.003); catalogued as CD1514580, COSV60337563; called by muse, mutect2, varscan2
- YOD1 | c.165C>G p.D55E | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV60007052; called by muse, mutect2, varscan2
- ZC3H7A | c.1230G>C p.Q410H | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV63271366; called by muse, mutect2, varscan2
- ZFP37 | c.1796A>T p.K599I | Missense Mutation (SNP) | VAF 113/343 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65288633; called by muse, mutect2, varscan2
- ZNF208 | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.412); catalogued as COSV68106624, COSV68112317, COSV68112595; called by muse, mutect2, varscan2
- ZP1 | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53926873; called by muse, mutect2, varscan2
- CDK2AP2 | c.57_71del p.G20_P24del | In Frame Del (DEL) | VAF 51/156 reads (33%) | called by mutect2, varscan2
- CHD1 | c.3061-5_3084del p.X1021_splice | Splice Site (DEL) | VAF 28/92 reads (30%) | called by mutect2, pindel, varscan2
- FRMD6 | c.1659del p.D554Tfs*104 (on ENST00000344768 / NM_001267046.2; = p.D546Tfs*104 on NM_152330.4) | Frame Shift Del (DEL) | VAF 118/284 reads (42%) | called by mutect2, pindel, varscan2
- NEDD1 | c.917_921+22del p.X306_splice | Splice Site (DEL) | VAF 20/98 reads (20%) | called by mutect2, pindel
- TMEM94 | c.1016_1033del p.A339_R344del | In Frame Del (DEL) | VAF 135/166 reads (81%) | called by mutect2, pindel, varscan2
- ARHGEF5 | c.732A>G p.G244= | Silent (SNP) | VAF 84/497 reads (17%) | catalogued as COSV50218849; called by muse, mutect2, varscan2
- ATG13 | c.963C>G p.T321= (on ENST00000359513 / NM_001346321.1; = p.T284= on NM_014741.4 and 9 other RefSeq transcripts) | Silent (SNP) | VAF 22/297 reads (7%) | catalogued as COSV100365935; called by muse, mutect2
- CACNA1F | c.4845C>T p.S1615= | Silent (SNP) | VAF 119/140 reads (85%) | catalogued as rs368972015, CD158407, COSV59906927; called by muse, mutect2, varscan2
- CDRT1 | c.1212T>C p.N404= | Silent (SNP) | VAF 134/155 reads (86%) | catalogued as COSV55413583; called by muse, mutect2, varscan2
- CHD5 | c.5397G>A p.A1799= | Silent (SNP) | VAF 33/35 reads (94%) | catalogued as rs376607024, COSV52424537; called by muse, mutect2, varscan2
- GPRC6A | c.1908C>T p.I636= | Silent (SNP) | VAF 12/430 reads (3%) | catalogued as COSV100114631; called by muse, mutect2
- IRS1 | c.840C>T p.I280= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as COSV59339917; called by muse, mutect2, varscan2
- NABP2 | c.384C>T p.D128= | Silent (SNP) | VAF 197/585 reads (34%) | catalogued as rs202142173, COSV57192405, COSV57193599; called by muse, mutect2, varscan2
- ORM2 | c.150T>C p.F50= | Silent (SNP) | VAF 199/657 reads (30%) | catalogued as COSV52281063; called by muse, mutect2, varscan2
- PLXNB3 | c.1170G>A p.L390= | Silent (SNP) | VAF 18/24 reads (75%) | catalogued as COSV62802036; called by muse, mutect2, varscan2
- TEPSIN | c.852G>T p.L284= | Silent (SNP) | VAF 16/16 reads (100%) | catalogued as COSV56144821; called by muse, mutect2, varscan2
- TMEM132D | c.291C>T p.Y97= | Silent (SNP) | VAF 97/414 reads (23%) | catalogued as rs760324975, COSV70622058; called by muse, mutect2, varscan2
- USP13 | c.1788C>G p.P596= | Silent (SNP) | VAF 186/539 reads (35%) | catalogued as COSV55866998, COSV55870761; called by muse, varscan2
- XPR1 | c.825C>G p.G275= | Silent (SNP) | VAF 44/103 reads (43%) | catalogued as COSV62557911, COSV62560469; called by muse, mutect2, varscan2
